Somatic mutation profile of tumor specimen ALCH-B78N-TTP1-A (aliquot ALCH-B78N-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B78N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,258 days).
Specimen ALCH-B78N-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea64d0d-925d-4a85-b931-27853141bba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B78N-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B78N-NB1-A-1-0-D-A96E-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4653bb9-a391-4b32-9f46-178cb28c9b87

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF1 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs923045719; called by muse, mutect2, varscan2
- CEP120 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs371963448; called by muse, mutect2, varscan2
- DNMBP | c.3381G>T p.K1127N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144358; called by muse, mutect2
- LRRC75B | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV50637990; called by muse, mutect2, varscan2
- MAPK7 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as rs746301619; called by muse, mutect2, varscan2
- PDE4A | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as COSV61797677; called by muse, varscan2
- PPA1 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs1247463712; called by muse, mutect2, varscan2
- PRSS22 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV50721751; called by muse, mutect2
- TDG | c.885A>C p.L295F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV99903947; called by muse, mutect2
- TTBK1 | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.242); catalogued as rs751716647, COSV52492832; called by muse, mutect2, varscan2
- DNAH6 | c.7786G>A p.V2596M | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXD2 | c.802G>A p.G268R (on ENST00000312994 / NM_001193362.1; = p.G143R on NM_018199.3) | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.047); called by muse, mutect2
- FADS3 | c.1124G>A p.W375* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- FBXW12 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2
- GATA5 | c.746C>A p.T249N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, varscan2
- KANK3 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, varscan2
- LZTS3 | c.712_721del p.L238Sfs*170 (on ENST00000329152; = p.L238Sfs*124 on NM_001282533.2) | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- NENF | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, varscan2
- OPLAH | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.914); called by muse, varscan2
- PAGR1 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PAQR9 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, varscan2
- RIOX2 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SLC25A10 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, varscan2
- TMC2 | c.1722C>A p.C574* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- CCSAP | c.318G>A p.A106= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- DCAF1 | c.195T>A p.A65= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- MAP1S | c.1098C>T p.G366= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1165643247; called by muse, varscan2
- PRR7 | c.468G>A p.A156= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1178963089; called by muse, varscan2
- SH3GL2 | c.732A>C p.I244= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- SLC8A3 | c.52C>T p.L18= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- SUSD4 | c.627C>G p.R209= | Silent (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- TBC1D10B | c.483T>G p.A161= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, varscan2
